Gene-level copy-number profile of tumor specimen MP2PRT-PAPAZA-TMP1-A from MP2PRT case MP2PRT-PAPAZA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,967 days).
Specimen MP2PRT-PAPAZA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 42724350-9869-4d89-ade6-2031d46b0433.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPAZA-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,253 have no estimate.
https://portal.gdc.cancer.gov/files/34d40404-d0cf-48c5-9974-3373b61c685d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 272; copy number 1: 1,337; copy number 2: 55,096; copy number 3: 1,665.

Homozygous deletions (total copy number 0; autosomes only): 272 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 41 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:90,114,838–90,173,414, 5 genes (within-gene range 0–1): IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,273,587–38,311,808, 6 genes (within-gene range 0–1): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.
- chr14:22,438,547–22,511,024, 40 genes (within-gene range 0–1): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr14:105,672,308–106,762,588, 161 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,032,745–22,058,892, 6 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3, IGLV10-67, AC245452.2, IGLVIV-66-1.
- chr22:22,168,289–22,230,469, 11 genes: AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
